Gene-level copy-number profile of tumor specimen TCGA-CD-8530-01A from TCGA case TCGA-CD-8530, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 52.0 years (18,992 days).
Specimen TCGA-CD-8530-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f733ef1c-8049-40b6-a9c9-7990a557e7dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-8530-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1ad03bf4-766f-474e-afb6-1a1496a86302

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 8,444; copy number 2: 37,221; copy number 3: 7,412; copy number 4: 6,026; copy number 5: 128; copy number 6: 5; copy number 7: 100; copy number 8: 17; copy number 10: 63; copy number 12: 73; copy number 13: 9; copy number 17: 26; copy number 22: 10; copy number 35: 272.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-8530-01A-11D-2338-01): tumor purity 0.19, ploidy 5.33, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 634 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–13,044,456, 363 genes, copy number 5–35 (broad region; genes not listed).
- chr10:77,912,271–80,145,359, 62 genes, copy number 7 (broad region; genes not listed).
- chr11:34,430,880–37,726,456, 47 genes, copy number 10–22: CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56.
- chr11:38,498,995–38,686,323, 3 genes, copy number 10: AC021713.1, LINC02759, LINC01493.
- chr11:41,122,907–45,235,110, 61 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr12:23,529,504–24,562,544, 1 gene, copy number 12 (within-gene range 3–12): SOX5.
- chr12:24,212,421–27,695,564, 72 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr13:33,355,206–34,928,076, 17 genes, copy number 8 (within-gene range 2–8): AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1.
- chr13:36,674,020–36,920,765, 8 genes, copy number 5: SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1.

Autosomal genes at a single copy (total copy number 1): 6,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
